Somatic mutation profile of tumor specimen ER-ABO1-TTP1-A (aliquot ER-ABO1-TTP1-A-1-0-D-A46U-34) from EXCEPTIONAL_RESPONDERS case ER-ABO1, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 27.3 years (9,955 days).
Specimen ER-ABO1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0380f40c-838e-4050-aeff-5701da0c0e53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ABO1-NT1-A (Solid Tissue Normal), aliquot ER-ABO1-NT1-A-1-0-D-A46U-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22006bb5-b44a-4127-89b0-2d2f4fb30bb8

The open-access MAF lists 13,675 somatic variants for this specimen: 9,247 protein-altering or splice-affecting, 3,552 silent, 876 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,367, Silent 3,552, Nonsense Mutation 420, 3'UTR 324, Intron 314, Frame Shift Ins 216, Splice Region 114, Splice Site 104, RNA 91, 5'UTR 85, 5'Flank 36, 3'Flank 26.

Variants (750 of 13,675; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs121908722, CM109816, CM930009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADA2 | c.1072G>A p.G358R (on ENST00000262607; = p.G117R on NM_177405.3) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs45511697, COSV52833624; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- ADGRG2 | c.1545dup p.E516* (on ENST00000379869 / NM_001079858.3; = p.E513* on NM_005756.4) | Frame Shift Ins (INS) | VAF 67/511 reads (13%) | catalogued as rs774488954; ClinVar: pathogenic; called by mutect2, varscan2
- ALAS2 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 90/164 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs137852311, CM114506, CM952463, CM990136; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANO3 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1478393931, COSV56797571; ClinVar: likely pathogenic; called by muse, varscan2
- ARID1B | c.5791C>T p.R1931* | Nonsense Mutation (SNP) | VAF 41/100 reads (41%) | catalogued as rs1028186690, COSV51647667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP1A2 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as rs755310507, CM075991; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP1A2 | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553245943, CM053782; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCL10 | c.136dup p.I46Nfs*4 | Frame Shift Ins (INS) | VAF 26/64 reads (41%) | catalogued as rs387906351; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA2 | c.5351dup p.N1784Kfs*3 | Frame Shift Ins (INS) | VAF 72/166 reads (43%) | catalogued as rs80359507; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CEP290 | c.2722C>T p.R908* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as rs886042153; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CHCHD2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs752169833, CM151627; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD8 | c.4414C>T p.R1472* (on ENST00000646647 / NM_001170629.2; = p.R1193* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 38/104 reads (37%) | catalogued as rs991738444, COSV63219638; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.3779+1G>A p.X1260_splice | Splice Site (SNP) | VAF 20/97 reads (21%) | catalogued as rs587783483, COSV52116972, COSV52125768, COSV52132996; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHTKD1 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as rs397514534, CM1211511; ClinVar: pathogenic; called by muse, varscan2
- DMD | c.3940C>T p.R1314* | Nonsense Mutation (SNP) | VAF 79/219 reads (36%) | catalogued as rs5030730, CM100263, CS002446, COSV63740877; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EARS2 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs376103091, CM123409; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by mutect2, varscan2
- EGLN1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs119476044, CM074153; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ESRP2 | c.974G>A p.R325H (on ENST00000565858 / NM_001365264.1; = p.R315H on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751873605, COSV52172250; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ETFA | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs119458970, CM920245; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.3508C>T p.R1170C | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs1366894709; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- FGD1 | c.2728C>T p.R910* | Nonsense Mutation (SNP) | VAF 129/321 reads (40%) | catalogued as rs1269514277; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FH | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913123, CM020705, CM031676, COSV100845105; ClinVar: pathogenic; called by muse, varscan2
- FOXP3 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs28935477, CM010059, COSV66050988; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GABRA1 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795283, COSV50115193; ClinVar: likely pathogenic; called by muse, varscan2
- GALT | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as rs111033737, CM990654, COSV66592755; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GLRA1 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199547699, CM104312, COSV51010888; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GNPTAB | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 42/114 reads (37%) | catalogued as rs281864969, CM100334, COSV54779528; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HNF4A | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as rs137853335, CD133296, CM971464, COSV57385535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IARS1 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 41/111 reads (37%) | catalogued as rs886037875, COSV65115700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- INPPL1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 35/83 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53353022, COSV99995692; called by muse, mutect2, varscan2
- KCNQ1 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs120074188, CM992172; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- LIG4 | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 33/106 reads (31%) | catalogued as rs104894418, CM014720, COSV63597683; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MC2R | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs104894660, CM002358, COSV59617811; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MED12 | c.4831C>T p.R1611C | Missense Mutation (SNP) | VAF 124/322 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs727503868, COSV100375342; ClinVar: likely pathogenic; called by muse, varscan2
- MSH6 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs779617676, CM144063, COSV52274821; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs727504240, CM992647; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MYH9 | c.5308C>T p.R1770C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1430793034, COSV99339343; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NAA15 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 59/134 reads (44%) | catalogued as rs1274633498, COSV56719543; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NDUFAF2 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as rs137852863, CM053986, COSV56942088; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 28/69 reads (41%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- PCSK9 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs793888521, CM164687; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PDHA1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863224148, CM920568, COSV63327821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PEX10 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 82/196 reads (42%) | catalogued as rs61750434, CM981515; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PEX6 | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as rs267608241, CM100015, COSV55102082; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 96/236 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PKLR | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773626254, CM941163; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKP2 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs754912778, CM1312958; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.1687C>T p.R563* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as rs587778618, CM102799, COSV56221094, COSV56222163; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PRF1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 130/243 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs200430442, CM040246; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PYGM | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370247862, CM030271; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1959dup p.V654Sfs*14 | Frame Shift Ins (INS) | VAF 57/225 reads (25%) | catalogued as rs1566234123; ClinVar: pathogenic; called by pindel, varscan2
- RRAS2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs782457908, COSV56329532; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RSPH3 | c.595C>T p.R199* (on ENST00000252655; = p.R57* on NM_031924.8) | Nonsense Mutation (SNP) | VAF 29/86 reads (34%) | catalogued as rs760122351, COSV51921181; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SDHA | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as rs771328239, COSV53769941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC4A4 | c.1661G>A p.R554H (on ENST00000264485 / NM_001098484.3; = p.R510H on NM_003759.4) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908857, CM992672; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPG11 | c.2697G>A p.W899* | Nonsense Mutation (SNP) | VAF 48/126 reads (38%) | catalogued as rs312262746, CM091365; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs786201090, CD044169, CM981870, COSV58820334, COSV58822715; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 35/122 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.3598C>T p.R1200W | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs45438205, CM961388; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TTN | c.64630C>T p.R21544* (on ENST00000591111; = p.R14120* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 42/105 reads (40%) | catalogued as rs878854328, COSV60187591; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- UBE2A | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 47/135 reads (35%) | catalogued as rs104894952, CM064349, COSV60636861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VDR | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909800, CM066612, CM961416, COSV99968922; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZNF462 | c.3898C>T p.R1300* | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | catalogued as rs1176008720; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as rs80353491; called by muse, mutect2, varscan2
- A4GALT | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs564938247, COSV50746524; called by muse, mutect2, varscan2
- AARS1 | c.2596G>A p.A866T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.268); catalogued as rs374478964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AARS1 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1383041194, COSV55746274; called by muse, mutect2, varscan2
- AATK | c.3320C>T p.P1107L (on ENST00000326724 / NM_001080395.3; = p.P1004L on NM_004920.2) | Missense Mutation (SNP) | VAF 114/308 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1204186816; called by muse, mutect2, varscan2
- ABAT | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs759472888; called by muse, mutect2, varscan2
- ABCA1 | c.5820G>A p.E1940= | Splice Region (SNP) | VAF 23/53 reads (43%) | catalogued as COSV66069117; called by muse, mutect2, varscan2
- ABCA1 | c.4025G>A p.R1342Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs576515619, COSV101036677; called by muse, mutect2, varscan2
- ABCA10 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 127/575 reads (22%) | catalogued as rs200246933, COSV52220026; called by muse, mutect2, varscan2
- ABCA12 | c.5089G>A p.D1697N (on ENST00000272895 / NM_173076.3; = p.D1379N on NM_015657.3) | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.602); catalogued as rs1265616723, COSV55953217; called by muse, mutect2, varscan2
- ABCA12 | c.2003A>G p.E668G (on ENST00000272895 / NM_173076.3; = p.E350G on NM_015657.3) | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV55966133; called by muse, mutect2, varscan2
- ABCA2 | c.5716G>A p.V1906I (on ENST00000614293; = p.V1876I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs775000577, COSV55800167; called by muse, mutect2, varscan2
- ABCA3 | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1567340152; called by muse, mutect2, varscan2
- ABCA4 | c.6250G>A p.A2084T | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250914690, COSV64671514, COSV64677755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA4 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs778392569, COSV64670688, COSV64677865; called by muse, varscan2
- ABCA6 | c.1615A>G p.T539A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs1290789719; called by muse, mutect2, varscan2
- ABCA7 | c.5885G>A p.R1962H | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV54031566; called by muse, mutect2, varscan2
- ABCA8 | c.2778+1G>A p.X926_splice | Splice Site (SNP) | VAF 50/123 reads (41%) | catalogued as rs1208294278; called by muse, mutect2, varscan2
- ABCA8 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs140949245; called by muse, mutect2, varscan2
- ABCB11 | c.2095T>A p.S699T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as CM103538; called by muse, mutect2
- ABCB6 | c.2419C>T p.R807* | Nonsense Mutation (SNP) | VAF 37/88 reads (42%) | catalogued as rs201568572; called by muse, mutect2, varscan2
- ABCB8 | c.1763C>T p.A588V (on ENST00000297504 / NM_001282291.2; = p.A571V on NM_007188.5) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780004246, COSV52503257; called by muse, mutect2, varscan2
- ABCC1 | c.3944T>C p.V1315A | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV104414939; called by muse, varscan2
- ABCC10 | c.2915C>T p.A972V (on ENST00000372530 / NM_001198934.2; = p.A944V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs774604430, COSV55088383; called by muse, mutect2, varscan2
- ABCC2 | c.890dup p.K298Efs*36 | Frame Shift Ins (INS) | VAF 22/62 reads (35%) | catalogued as rs759781877; called by mutect2, varscan2
- ABCC5 | c.4300G>A p.A1434T | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs553921855, COSV99657448; called by muse, mutect2, varscan2
- ABCC5 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs772502692, COSV55593298; called by muse, mutect2, varscan2
- ABCC6 | c.4130C>T p.T1377M | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs371122482; called by muse, mutect2, varscan2
- ABCC6 | c.3016A>G p.M1006V | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs762192080; called by muse, mutect2
- ABCC9 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 160/386 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs75460545, COSV53962326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD1 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.474); catalogued as rs782693577; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ABCD1 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as CM990147; called by muse, mutect2, varscan2
- ABCF3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs376213461; called by muse, mutect2, varscan2
- ABCG1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.298); catalogued as rs750984103; called by muse, mutect2, varscan2
- ABCG1 | c.1978A>G p.I660V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1203293043; called by muse, mutect2, varscan2
- ABCG5 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99571359; called by muse, mutect2, varscan2
- ABCG8 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs745365455, COSV55394055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG8 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs759147053, COSV55396094; called by muse, mutect2, varscan2
- ABHD16B | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs142426403; called by muse, mutect2, varscan2
- ABHD8 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99917255; called by muse, mutect2, varscan2
- ABHD8 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs755933630; called by muse, mutect2, varscan2
- ABI3BP | c.1441A>C p.S481R | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV52529186; called by muse, mutect2, varscan2
- ABL1 | c.2144G>A p.R715H | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.99); catalogued as rs571264328, COSV59334221; called by muse, mutect2, varscan2
- ABR | c.725G>A p.R242Q (on ENST00000302538 / NM_021962.5; = p.R205Q on NM_001092.5) | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767566925; called by muse, mutect2, varscan2
- ABRAXAS1 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs763021007; called by muse, mutect2, varscan2
- ABRAXAS2 | c.776G>T p.R259I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV53716687; called by muse, mutect2, varscan2
- AC005324.2 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as rs759354072; called by muse, mutect2, varscan2
- AC009879.2 | c.-100A>G | Splice Region (SNP) | VAF 62/167 reads (37%) | catalogued as rs902283566; called by muse, mutect2, varscan2
- AC011448.1 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772369943, COSV52272272, COSV52276334; called by muse, mutect2, varscan2
- AC011455.2 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 76/166 reads (46%) | catalogued as COSV99671307; called by muse, mutect2, varscan2
- AC100868.1 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.54); catalogued as COSV51839006, COSV51847846; called by muse, mutect2, varscan2
- AC109583.1 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs201477242; called by muse, mutect2, varscan2
- AC244197.3 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as rs782697859, COSV61711610; called by muse, mutect2
- ACAA1 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs374655368; called by muse, mutect2, varscan2
- ACACA | c.4663C>T p.R1555C | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs762798712; called by muse, varscan2
- ACACB | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs777523810; called by muse, mutect2, varscan2
- ACACB | c.6995G>A p.R2332H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778545831, COSV58129922; called by muse, mutect2, varscan2
- ACADSB | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs368438650, COSV62551325; called by muse, varscan2
- ACAP1 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV50135891; called by muse, mutect2, varscan2
- ACE | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs989791368, COSV52007304; called by muse, mutect2, varscan2
- ACO1 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774091732; called by muse, mutect2, varscan2
- ACOD1 | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.173); catalogued as rs1442617397; called by muse, mutect2, varscan2
- ACOT13 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1187354026; called by muse, mutect2, varscan2
- ACOT7 | c.1001C>T p.S334L (on ENST00000377855 / NM_181864.3; = p.S324L on NM_007274.4) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754935873, COSV64111710; called by muse, mutect2, varscan2
- ACOX2 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs530318063, COSV57150824; called by muse, mutect2, varscan2
- ACRBP | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as rs1330734716; called by muse, mutect2, varscan2
- ACSBG1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs762790030; called by muse, mutect2, varscan2
- ACSL4 | c.1125G>A p.P375= (on ENST00000340800 / NM_022977.2; = p.P334= on NM_004458.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 188/483 reads (39%) | catalogued as rs763924578, COSV100539134; called by muse, varscan2
- ACSL6 | c.1624G>A p.G542R (on ENST00000379240; = p.G567R on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs543745359, COSV57305596; called by muse, mutect2, varscan2
- ACSM1 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs145170042; called by muse, varscan2
- ACSM2B | c.996G>T p.Q332H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV61657261; called by muse, mutect2
- ACSS1 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as rs775016558, COSV60222349; called by muse, mutect2, varscan2
- ACTL6A | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); catalogued as COSV66998640; called by muse, mutect2, varscan2
- ACTL7B | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs758754533; called by muse, mutect2, varscan2
- ACTN1 | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as rs1468329163, COSV99518838; called by muse, mutect2, varscan2
- ACTN2 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.412); catalogued as rs370865082, COSV100856455; called by muse, mutect2, varscan2
- ACTN3 | c.2337G>T p.M779I | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59751172; called by muse, mutect2
- ACTN4 | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV53150227; called by muse, mutect2, varscan2
- ACTR1B | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs374344795; called by muse, mutect2, varscan2
- ACTR8 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs1239745813, COSV51636480; called by muse, mutect2, varscan2
- ADA | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as rs776103734, COSV65741032; called by muse, mutect2, varscan2
- ADAM20 | c.1817G>A p.G606D | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371919442; called by muse, mutect2, varscan2
- ADAM20 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs575058707; called by muse, mutect2, varscan2
- ADAM21 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs149756061, COSV50792703; called by muse, varscan2
- ADAM23 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 115/265 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.315); catalogued as rs201146986; called by muse, mutect2, varscan2
- ADAM29 | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs778936442; called by muse, mutect2, varscan2
- ADAM30 | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.6); catalogued as rs766145128; called by muse, mutect2, varscan2
- ADAM33 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs867486660; called by muse, mutect2, varscan2
- ADAM33 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs537682740; called by muse, mutect2, varscan2
- ADAMTS13 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs140937290, COSV63020403; called by muse, mutect2, varscan2
- ADAMTS15 | c.2836G>A p.V946I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs772012411, COSV54508751; called by muse, mutect2, varscan2
- ADAMTS17 | c.3266G>A p.R1089H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs759480599, COSV51484383; called by muse, mutect2, varscan2
- ADAMTS17 | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs780220308; called by muse, mutect2, varscan2
- ADAMTS19 | c.3094G>A p.A1032T | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs746700188, COSV50757439, COSV50788853, COSV50800289; called by muse, mutect2, varscan2
- ADAMTS4 | c.2069G>A p.G690D | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs1248691991; called by muse, mutect2, varscan2
- ADAMTS4 | c.1190A>C p.H397P | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV100917584; called by muse, mutect2
- ADAMTS7 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1272927381; called by muse, varscan2
- ADAMTS8 | c.1832T>C p.V611A | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV57292474; called by muse, mutect2, varscan2
- ADAMTS9 | c.3559C>T p.R1187* | Nonsense Mutation (SNP) | VAF 29/75 reads (39%) | catalogued as COSV55782247; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368824783; called by muse, mutect2, varscan2
- ADAP1 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762723014; called by muse, mutect2, varscan2
- ADAR | c.1182A>G p.I394M | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs1310407073; called by muse, mutect2, varscan2
- ADCK5 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs921386378; called by muse, mutect2, varscan2
- ADCY3 | c.3307C>T p.R1103* | Nonsense Mutation (SNP) | VAF 59/170 reads (35%) | catalogued as rs746113754, COSV53170471; called by muse, mutect2, varscan2
- ADCY5 | c.3623G>A p.R1208H | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1064797295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY6 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781510708, COSV100326887; called by muse, mutect2, varscan2
- ADCY6 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs1158355413; called by muse, varscan2
- ADD1 | c.741G>A p.A247= | Splice Region (SNP) | VAF 82/174 reads (47%) | catalogued as rs781377661; called by muse, mutect2, varscan2
- ADGB | c.3197C>T p.A1066V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as rs558119202, COSV62222994; called by muse, mutect2, varscan2
- ADGRA1 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.029); catalogued as rs774780372; called by muse, mutect2, varscan2
- ADGRA2 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs147459946, COSV100178112; called by muse, mutect2, varscan2
- ADGRA3 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.976); catalogued as rs144734405; called by muse, mutect2, varscan2
- ADGRB1 | c.1318dup p.Q440Pfs*8 | Frame Shift Ins (INS) | VAF 50/134 reads (37%) | catalogued as rs772974645; called by mutect2, varscan2
- ADGRB2 | c.2701G>A p.A901T | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.088); catalogued as rs1176380521; called by muse, mutect2, varscan2
- ADGRD1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.065); catalogued as rs368468703, COSV104377062; called by muse, mutect2, varscan2
- ADGRD2 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.063); catalogued as rs376234772; called by muse, varscan2
- ADGRF1 | c.2053C>T p.R685W | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs368585261; called by muse, mutect2, varscan2
- ADGRF3 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1393284176; called by muse, mutect2, varscan2
- ADGRF5 | c.3214G>A p.A1072T | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs751080249, COSV99345245; called by muse, mutect2, varscan2
- ADGRG4 | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV54952200; called by muse, mutect2, varscan2
- ADGRG4 | c.5827T>C p.S1943P | Missense Mutation (SNP) | VAF 141/354 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54950105; called by muse, varscan2
- ADGRG4 | c.8630G>T p.G2877V | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99796389; called by muse, mutect2, varscan2
- ADGRG5 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758492374, COSV61082714; called by muse, mutect2, varscan2
- ADGRL1 | c.4043G>A p.R1348Q (on ENST00000340736 / NM_001008701.3; = p.R1343Q on NM_014921.5) | Missense Mutation (SNP) | VAF 99/262 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs773938056; called by muse, mutect2, varscan2
- ADGRV1 | c.3179C>T p.T1060M | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs768978840, COSV101316274; called by muse, mutect2, varscan2
- ADGRV1 | c.3364dup p.S1122Ffs*15 | Frame Shift Ins (INS) | VAF 56/142 reads (39%) | catalogued as rs779424764; called by mutect2, pindel, varscan2
- ADPRH | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.051); catalogued as rs201509638; called by muse, mutect2, varscan2
- ADPRHL1 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768500663, COSV62910453; called by muse, mutect2, varscan2
- AFAP1L2 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756020219; called by muse, mutect2, varscan2
- AFAP1L2 | c.222G>A p.A74= | Splice Region (SNP) | VAF 30/78 reads (38%) | catalogued as rs1056689188; called by muse, mutect2, varscan2
- AFDN | c.4333C>T p.R1445C | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs775819918, COSV60059797; called by muse, mutect2, varscan2
- AFF3 | c.2701C>T p.R901* | Nonsense Mutation (SNP) | VAF 84/242 reads (35%) | catalogued as rs201416603; called by muse, varscan2
- AFF3 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs1483457558; called by muse, varscan2
- AFP | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs1416037419; called by muse, mutect2, varscan2
- AGAP1 | c.1846C>T p.R616W (on ENST00000304032 / NM_001037131.3; = p.R563W on NM_014914.5) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1380892182, COSV58320744; called by muse, mutect2, varscan2
- AGAP1 | c.2171C>T p.P724L (on ENST00000304032 / NM_001037131.3; = p.P671L on NM_014914.5) | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746826800; called by muse, mutect2, varscan2
- AGAP2 | c.1709G>A p.R570H (on ENST00000547588 / NM_001122772.2; = p.R234H on NM_014770.4) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs769607256, COSV57726906; called by muse, mutect2, varscan2
- AGAP2 | c.1372C>T p.R458* (on ENST00000547588 / NM_001122772.2; = p.R122* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 37/92 reads (40%) | catalogued as rs772467140, COSV57727647; called by muse, mutect2, varscan2
- AGAP4 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1163083723; called by muse, mutect2, varscan2
- AGAP6 | c.1910C>T p.A637V (on ENST00000374056 / NM_001365867.1; = p.A660V on NM_001077665.2) | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1265928178, COSV65018027; called by muse, mutect2, varscan2
- AGBL4 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs759711843, COSV100887040; called by muse, mutect2, varscan2
- AGMO | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751893917, COSV61111511; called by muse, mutect2, varscan2
- AGO2 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs777295689; called by muse, mutect2, varscan2
- AGO4 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs773809553, COSV64616987; called by muse, mutect2, varscan2
- AGPAT3 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368482; called by muse, mutect2, varscan2
- AGPAT3 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs370780500; called by muse, mutect2, varscan2
- AGRN | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as rs377657804; called by muse, mutect2, varscan2
- AGRN | c.3860G>A p.R1287Q | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs1236736432, COSV65070546; called by muse, mutect2, varscan2
- AGRP | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs1341815023; called by muse, mutect2, varscan2
- AGTPBP1 | c.3257G>A p.R1086H (on ENST00000357081 / NM_001330701.2; = p.R1046H on NM_015239.2) | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100429483; called by muse, mutect2, varscan2
- AGTR1 | c.1080A>G p.*360Wext*9 | Nonstop Mutation (SNP) | VAF 45/142 reads (32%) | catalogued as rs778604981; called by muse, mutect2, varscan2
- AHNAK | c.11360A>G p.D3787G | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as rs769094763; called by muse, mutect2, varscan2
- AHNAK2 | c.15139C>T p.P5047S | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs775209089; called by muse, mutect2, varscan2
- AHNAK2 | c.13112T>C p.V4371A | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.821); catalogued as rs1159932106, COSV100317856; called by muse, mutect2, varscan2
- AHNAK2 | c.8258T>C p.V2753A | Missense Mutation (SNP) | VAF 119/283 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.088); catalogued as rs773899204; called by muse, mutect2, varscan2
- AIM2 | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs866050462, COSV63698814; called by muse, mutect2, varscan2
- AIRE | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs771314896; called by muse, mutect2, varscan2
- AJAP1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as rs762630841; called by muse, mutect2, varscan2
- AJM1 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 104/267 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs1325390224, COSV56032008; called by muse, mutect2, varscan2
- AKAP10 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 145/350 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1322956127; called by muse, mutect2, varscan2
- AKAP11 | c.4877G>A p.R1626H | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs150888197; called by muse, mutect2, varscan2
- AKAP17A | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 141/380 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs766136204; called by muse, mutect2, varscan2
- AKAP8L | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as rs751938604, COSV101275853; called by muse, mutect2, varscan2
- AKR1B1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as rs780615158, COSV53648254; called by muse, mutect2, varscan2
- AKT1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1566818890, COSV62573359; called by muse, mutect2, varscan2
- AKT2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.146); catalogued as rs746407532; called by muse, mutect2, varscan2
- AL035460.1 | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs951716539; called by muse, mutect2, varscan2
- AL121899.2 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs759655716; called by muse, mutect2, varscan2
- AL121899.2 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs763049283; called by muse, mutect2, varscan2
- AL121899.2 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs776091527; called by muse, mutect2, varscan2
- AL162417.1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 108/284 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs140076798; called by muse, mutect2, varscan2
- ALCAM | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 136/334 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs374209704; called by muse, varscan2
- ALDH18A1 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745614904, COSV100973306; called by muse, mutect2, varscan2
- ALDH1A1 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs762664992, COSV52793255; called by muse, mutect2, varscan2
- ALDH3B1 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs1346406531; called by muse, mutect2, varscan2
- ALDH4A1 | c.1567dup p.A523Gfs*8 | Frame Shift Ins (INS) | VAF 26/68 reads (38%) | catalogued as rs754334877; called by mutect2, varscan2
- ALDOB | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs780442649, COSV66398306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG1 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 76/206 reads (37%) | catalogued as rs1239451251; called by muse, mutect2, varscan2
- ALG12 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 34/89 reads (38%) | PolyPhen probably damaging (1); catalogued as rs777719396; called by muse, mutect2, varscan2
- ALG12 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 38/107 reads (36%) | PolyPhen benign (0.007); catalogued as rs534700632; called by muse, mutect2, varscan2
- ALG2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770060939; called by muse, mutect2, varscan2
- ALKBH3 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs202134415; called by muse, mutect2, varscan2
- ALKBH3 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as rs759461489; called by muse, mutect2, varscan2
- ALLC | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs750935372, COSV52994991; called by muse, mutect2, varscan2
- ALOX5 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs778418203; called by muse, mutect2, varscan2
- ALPK1 | c.3691C>T p.R1231C | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.203); catalogued as rs765867621; called by muse, mutect2, varscan2
- ALPK2 | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV64495725; called by muse, mutect2, varscan2
- ALPK3 | c.1853T>C p.V618A | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1000115945; called by muse, mutect2, varscan2
- ALS2 | c.4763C>T p.A1588V | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as rs540726634; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALS2CL | c.2825G>A p.R942H | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs144181784, COSV100015192; called by muse, mutect2, varscan2
- AMBRA1 | c.2156C>T p.A719V (on ENST00000458649 / NM_001367468.1; = p.A629V on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.665); catalogued as rs775965143, COSV54057607; called by muse, mutect2, varscan2
- AMD1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV64387453; called by muse, mutect2, varscan2
- AMER1 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs947597246; called by muse, mutect2, varscan2
- AMFR | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs766511582, COSV51922857; called by muse, mutect2, varscan2
- AMHR2 | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57687343; called by muse, mutect2, varscan2
- AMPD1 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs61757695; called by muse, mutect2, varscan2
- AMPD1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs140601541, COSV100814850; called by muse, mutect2, varscan2
- AMPD2 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs903900201; called by muse, mutect2, varscan2
- AMY1C | c.981A>G p.I327M | Missense Mutation (SNP) | VAF 88/434 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1334045329; called by muse, mutect2, varscan2
- AMY2A | c.169-1G>A p.X57_splice | Splice Site (SNP) | VAF 157/397 reads (40%) | catalogued as rs770998615; called by muse, mutect2, varscan2
- ANAPC5 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs1315919690; called by muse, mutect2, varscan2
- ANAPC5 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99946099; called by muse, mutect2, varscan2
- ANAPC7 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as rs562414935, COSV101484780; called by mutect2, varscan2
- ANGPTL2 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1484591884; called by muse, mutect2, varscan2
- ANGPTL3 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 101/263 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1370075838; called by muse, mutect2, varscan2
- ANK1 | c.3443G>A p.R1148Q | Missense Mutation (SNP) | VAF 133/305 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as rs771237247, COSV55873730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1375977442; called by muse, mutect2, varscan2
- ANK2 | c.3467G>A p.R1156H | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765509936, COSV52147974; called by muse, mutect2, varscan2
- ANKAR | c.2597G>A p.G866D | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs759913441; called by muse, mutect2, varscan2
- ANKEF1 | c.1409G>A p.R470K | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs758729366; called by muse, mutect2, varscan2
- ANKH | c.994A>G p.M332V | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52485346; called by muse, mutect2, varscan2
- ANKRD10 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57444860; called by muse, varscan2
- ANKRD10 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.085); catalogued as rs140149224; called by muse, mutect2, varscan2
- ANKRD10 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 53/140 reads (38%) | catalogued as COSV57443365; called by muse, mutect2, varscan2
- ANKRD11 | c.7564G>A p.E2522K | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56366745; called by muse, mutect2, varscan2
- ANKRD11 | c.4970C>T p.S1657L | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs749114664, COSV56362701; called by muse, mutect2, varscan2
- ANKRD13D | c.*1542-2A>G | Splice Site (SNP) | VAF 34/67 reads (51%) | catalogued as COSV100354277; called by muse, mutect2, varscan2
- ANKRD16 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs138291670; called by muse, mutect2, varscan2
- ANKRD17 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV58229744; called by muse, varscan2
- ANKRD2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs773670423, COSV100081023; called by muse, mutect2, varscan2
- ANKRD27 | c.2215G>A p.V739M | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as rs771538899, COSV60131959; called by muse, mutect2, varscan2
- ANKRD34B | c.672G>A p.W224* | Nonsense Mutation (SNP) | VAF 60/129 reads (47%) | catalogued as rs780854492; called by muse, varscan2
- ANKRD35 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as rs145335153; called by muse, mutect2, varscan2
- ANKRD44 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs754432821; called by muse, mutect2, varscan2
- ANKRD44 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs947678457, COSV56549495; called by muse, varscan2
- ANKRD52 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as rs781048841; called by muse, varscan2
- ANKRD6 | c.1328T>C p.M443T | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs771132647; called by muse, mutect2, varscan2
- ANKS1A | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs752776147; called by muse, mutect2
- ANKS1B | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs542524400; called by muse, mutect2, varscan2
- ANKS3 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as rs776169640, COSV100422800; called by muse, mutect2, varscan2
- ANKS6 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs767907988, COSV62051272; called by muse, mutect2, varscan2
- ANKZF1 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs545546589, COSV55478697; called by muse, mutect2, varscan2
- ANO1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.311); catalogued as rs34716436; called by muse, mutect2, varscan2
- ANO10 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 212/537 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs140132703; called by muse, varscan2
- ANO2 | c.2225A>G p.Y742C (on ENST00000356134 / NM_001278597.3; = p.Y746C on NM_001278596.3) | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1243208753; called by muse, mutect2, varscan2
- ANO2 | c.371A>G p.N124S (on ENST00000356134 / NM_001278597.3; = p.N128S on NM_001278596.3) | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.236); catalogued as rs762033755; called by muse, mutect2
- ANO3 | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs1343866619, COSV56808683; called by muse, varscan2
- ANO7 | c.1042G>A p.A348T (on ENST00000274979; = p.A294T on NM_001370694.2) | Missense Mutation (SNP) | VAF 69/400 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs761832893; called by muse, varscan2
- ANTKMT | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1158046995; called by muse, mutect2, varscan2
- ANXA11 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs539605721; called by muse, mutect2, varscan2
- ANXA9 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776885513, COSV56497500; called by muse, mutect2, varscan2
- AP000812.4 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs780468292; called by muse, mutect2, varscan2
- AP1B1 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs1476667715; called by muse, mutect2, varscan2
- AP1M2 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as rs748277918; called by muse, mutect2, varscan2
- AP3D1 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1452569078; called by muse, varscan2
- AP3D1 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1189849965, COSV61425560; called by muse, varscan2
- AP4E1 | c.2708C>T p.A903V | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs750861543; called by muse, mutect2, varscan2
- AP4M1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs369201294; called by muse, mutect2, varscan2
- AP5B1 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.054); catalogued as rs1173856442; called by muse, mutect2, varscan2
- AP5Z1 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs1056631913; called by muse, mutect2, varscan2
- AP5Z1 | c.2333G>A p.R778H | Missense Mutation (SNP) | VAF 101/237 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs759530942; called by muse, mutect2, varscan2
- APBA1 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs1488264997; called by muse, mutect2, varscan2
- APC | c.4225C>T p.P1409S | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99971627; called by muse, mutect2, varscan2
- APC2 | c.2972G>A p.R991H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs781675307, COSV104374081; called by muse, mutect2, varscan2
- APCDD1L | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs767000055; called by muse, mutect2, varscan2
- APEX2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 141/321 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as rs866601451, COSV66624500; called by muse, mutect2, varscan2
- APLP1 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as COSV99697631; called by muse, mutect2, varscan2
- APLP2 | c.2089G>A p.G697S | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755287713, COSV53840976; called by muse, mutect2, varscan2
- APMAP | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs201595930, COSV54177352; called by muse, mutect2, varscan2
- APOA5 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs752093878, COSV99911368; called by muse, mutect2, varscan2
- APOB | c.11965C>T p.R3989C | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs150713761, COSV51926700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs749139535, COSV57550081; called by muse, mutect2, varscan2
- APOBEC3C | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs200673371, COSV63865404, COSV63865753; called by muse, mutect2, varscan2
- APOBEC3C | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772415284, COSV53326461; called by muse, varscan2
- APOBEC3G | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 133/349 reads (38%) | catalogued as rs779756048, COSV101349075; called by muse, mutect2, varscan2
- APOBEC3G | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs199763152, COSV68470823; called by muse, mutect2, varscan2
- APOE | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs778237451; called by muse, mutect2, varscan2
- APP | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200500889; called by muse, mutect2, varscan2
- APPBP2 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs955608097, COSV50031153; called by muse, mutect2, varscan2
- APPL2 | c.416-7T>G | Splice Region (SNP) | VAF 32/137 reads (23%) | catalogued as rs747193696; called by muse, mutect2, varscan2
- AQP1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs748039521, COSV61266109; called by muse, mutect2, varscan2
- ARAP1 | c.3235C>T p.R1079W (on ENST00000393609 / NM_001040118.2; = p.R834W on NM_015242.4) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146883151; called by muse, mutect2, varscan2
- ARAP1 | c.829G>A p.D277N (on ENST00000393609 / NM_001040118.2; = p.D32N on NM_015242.4) | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs775610852, COSV61994086; called by muse, varscan2
- AREG | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 130/366 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); catalogued as COSV99144393; called by muse, mutect2, varscan2
- AREL1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs757996581, COSV100707656; called by muse, mutect2, varscan2
- ARF3 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV56741604; called by muse, varscan2
- ARFGAP3 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs756482945, COSV54311590; called by muse, mutect2, varscan2
- ARFGEF2 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV64211831, COSV64212304; called by muse, mutect2, varscan2
- ARFGEF3 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs1164308106, COSV99293078; called by muse, mutect2, varscan2
- ARHGAP11A | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs143960378, COSV64381612; called by muse, mutect2, varscan2
- ARHGAP20 | c.3506C>T p.A1169V | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs200417489; called by muse, mutect2, varscan2
- ARHGAP21 | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 48/102 reads (47%) | catalogued as COSV57610116; called by muse, mutect2, varscan2
- ARHGAP23 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1263320474; called by muse, mutect2, varscan2
- ARHGAP24 | c.1301C>T p.T434I (on ENST00000395184 / NM_001025616.3; = p.T341I on NM_031305.3) | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1043404313, COSV51993849; called by muse, mutect2, varscan2
- ARHGAP24 | c.2104C>T p.R702* (on ENST00000395184 / NM_001025616.3; = p.R609* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 94/245 reads (38%) | catalogued as rs376118883; called by mutect2, varscan2
- ARHGAP32 | c.4982A>G p.Y1661C (on ENST00000310343 / NM_001378025.1; = p.Y1312C on NM_014715.4) | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); catalogued as rs1022492381; called by muse, mutect2, varscan2
- ARHGAP33 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV99138275; called by muse, mutect2
- ARHGAP33 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 92/251 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV50169995; called by muse, mutect2, varscan2
- ARHGAP33 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs373692589, COSV50131638; called by mutect2, varscan2
- ARHGAP33 | c.3230C>T p.A1077V | Missense Mutation (SNP) | VAF 129/330 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as rs1387996770, COSV50120126; called by muse, mutect2, varscan2
- ARHGAP35 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 47/106 reads (44%) | catalogued as rs1324454897, COSV68329190; called by muse, mutect2, varscan2
- ARHGAP35 | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 47/119 reads (39%) | catalogued as COSV68330848; called by muse, mutect2, varscan2
- ARHGAP45 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1371398651; called by muse, mutect2
- ARHGAP9 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1201357420; called by muse, mutect2, varscan2
- ARHGEF10L | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 78/468 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs776421443, COSV51436665; called by muse, mutect2, varscan2
- ARHGEF10L | c.2972G>A p.R991Q | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747529935; called by muse, mutect2, varscan2
- ARHGEF10L | c.3019G>A p.E1007K | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs1238254004, COSV99391969; called by muse, mutect2, varscan2
- ARHGEF12 | c.2957G>A p.R986H | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs767481639, COSV63107823; called by muse, varscan2
- ARHGEF12 | c.2977C>T p.R993C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766559873, COSV63104399; called by muse, varscan2
- ARHGEF18 | c.505G>A p.A169T (on ENST00000359920 / NM_001130955.2; = p.A65T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs760864454; called by muse, mutect2, varscan2
- ARHGEF18 | c.2101C>T p.R701* (on ENST00000359920 / NM_001130955.2; = p.R597* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 59/139 reads (42%) | catalogued as COSV60469496; called by muse, mutect2, varscan2
- ARHGEF2 | c.104G>A p.R35H (on ENST00000361247 / NM_001162383.2; = p.R8H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1174401642, COSV58116154; called by muse, mutect2, varscan2
- ARHGEF28 | c.4391C>T p.A1464V | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs1364181337; called by muse, mutect2, varscan2
- ARHGEF3 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs201007278; called by muse, mutect2, varscan2
- ARHGEF5 | c.3185C>T p.P1062L | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs781507585; called by mutect2, varscan2
- ARID1A | c.6212T>C p.L2071S | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61384061; called by muse, mutect2, varscan2
- ARID2 | c.3817C>T p.R1273* | Nonsense Mutation (SNP) | VAF 51/131 reads (39%) | catalogued as COSV57603720, COSV57615266; called by muse, mutect2, varscan2
- ARID3A | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs143073569; called by muse, mutect2, varscan2
- ARID5B | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1210330333; called by muse, mutect2, varscan2
- ARMC3 | c.974T>C p.L325S | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53068592; called by muse, mutect2, varscan2
- ARMC4 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV53464285; called by muse, mutect2, varscan2
- ARMC5 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768581053; called by muse, varscan2
- ARMC5 | c.2561C>T p.A854V | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.998); catalogued as rs1334144375, COSV51659007, COSV51660023; called by muse, varscan2
- ARMH1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs868501844; called by muse, mutect2, varscan2
- ARNT | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490240303, COSV100590925, COSV62229602; called by muse, mutect2, varscan2
- ARPC1A | c.983+1G>A p.X328_splice | Splice Site (SNP) | VAF 19/51 reads (37%) | catalogued as rs1385482184; called by muse, mutect2, varscan2
- ARPP21 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 97/236 reads (41%) | catalogued as rs545003470, COSV51799381; called by muse, mutect2, varscan2
- ARRDC4 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1247827755, COSV51418426, COSV99164327; called by muse, mutect2, varscan2
- ARSH | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs777648295, COSV66963765; called by muse, mutect2, varscan2
- ARSJ | c.1201T>C p.Y401H | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as rs1439308706; called by muse, mutect2, varscan2
- ASAP2 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 92/203 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs374864722, COSV55634932; called by muse, mutect2, varscan2
- ASB12 | c.955T>C p.*319Qext*9 | Nonstop Mutation (SNP) | VAF 44/150 reads (29%) | catalogued as rs1569197874; called by muse, mutect2, varscan2
- ASB15 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs760105269, COSV51925037; called by muse, mutect2, varscan2
- ASB16 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs150509579; called by muse, mutect2, varscan2
- ASCC1 | c.983C>T p.A328V (on ENST00000342444 / NM_001369085.1; = p.A300V on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs774939192, COSV57727423; called by muse, varscan2
- ASH1L | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs768527981; called by muse, mutect2, varscan2
- ASIC1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.122); catalogued as rs762242221; called by muse, mutect2, varscan2
- ASIC2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.871); catalogued as COSV63309139; called by muse, mutect2, varscan2
- ASIC3 | c.1518-5C>T | Splice Region (SNP) | VAF 62/188 reads (33%) | catalogued as rs748736458, COSV99877266; called by muse, varscan2
- ASIC4 | c.1367G>A p.R456Q (on ENST00000347842 / NM_182847.3; = p.R475Q on NM_018674.6) | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs753563170; called by muse, mutect2, varscan2
- ASNSD1 | c.1703A>G p.E568G | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs1305819636; called by muse, mutect2, varscan2
- ASPH | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs1202877763, COSV62860407; called by muse, mutect2, varscan2
- ASPHD1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs1373928503, COSV100435332; called by muse, mutect2, varscan2
- ASPHD2 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs1409507692, COSV53220784; called by muse, varscan2
- ASPM | c.8524C>T p.R2842W | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs112946633; ClinVar: uncertain significance; called by muse, varscan2
- ASPM | c.4897C>T p.R1633C | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as rs200202166; called by muse, mutect2, varscan2
- ASPM | c.4495C>T p.R1499W | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756067585, COSV54125044; called by muse, mutect2, varscan2
- ASPM | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99660716; called by muse, mutect2, varscan2
- ASPM | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54136754; called by muse, mutect2, varscan2
- ASPSCR1 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 137/305 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs776182994, COSV60727639; called by muse, mutect2, varscan2
- ASTN1 | c.3020C>T p.S1007F | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.667); catalogued as rs749519929; called by muse, varscan2
- ASTN1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs762828793, COSV56070182, COSV99923743; called by muse, mutect2, varscan2
- ASXL1 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as rs147895689; called by muse, mutect2, varscan2
- ATAD1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 91/220 reads (41%) | catalogued as rs771096246; called by muse, mutect2, varscan2
- ATAD5 | c.2567C>T p.A856V | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs768638862; called by muse, varscan2
- ATAD5 | c.2611G>A p.V871I | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs140072712; called by muse, varscan2
- ATAT1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs753361191; called by muse, mutect2, varscan2
- ATF7 | c.680C>T p.P227L (on ENST00000548446 / NM_001366555.2; = p.P216L on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs978219733, COSV60643919; called by muse, mutect2, varscan2
- ATG2A | c.5566G>A p.D1856N | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs373838276; called by muse, mutect2, varscan2
- ATG2A | c.3106C>T p.R1036C | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as rs760180909, COSV65966277; called by muse, mutect2, varscan2
- ATG2B | c.2880G>A p.R960= | Splice Region (SNP) | VAF 101/271 reads (37%) | catalogued as COSV63423400; called by muse, mutect2, varscan2
- ATG4C | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 178/481 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.075); catalogued as rs750198093; called by muse, mutect2, varscan2
- ATG4D | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.39); catalogued as rs781203664; called by muse, mutect2, varscan2
- ATM | c.7210T>C p.Y2404H | Missense Mutation (SNP) | VAF 84/424 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53729956; called by muse, mutect2, varscan2
- ATOH1 | c.24A>C p.E8D | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.265); catalogued as rs896790063; called by muse, mutect2, varscan2
- ATP10A | c.3240G>A p.W1080* | Nonsense Mutation (SNP) | VAF 12/160 reads (8%) | catalogued as rs1312374945; called by muse, mutect2
- ATP10A | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.059); catalogued as rs767644611, COSV63516289; called by muse, varscan2
- ATP10A | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758536427, COSV63523642; called by muse, varscan2
- ATP10A | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs776815675, COSV100791706, COSV63517157; called by muse, mutect2, varscan2
- ATP10B | c.4333C>T p.R1445W | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs761953300; called by muse, mutect2, varscan2
- ATP11B | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 48/139 reads (35%) | catalogued as COSV60029761; called by muse, mutect2, varscan2
- ATP13A2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as rs536805463; called by muse, mutect2, varscan2
- ATP1A2 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753517155; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A3 | c.2333C>T p.S778F (on ENST00000545399 / NM_001256214.2; = p.S765F on NM_152296.5) | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57492253; called by muse, mutect2, varscan2
- ATP1B1 | c.51G>A p.W17* | Nonsense Mutation (SNP) | VAF 125/322 reads (39%) | catalogued as COSV63180364; called by muse, mutect2, varscan2
- ATP1B2 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.253); catalogued as rs770644298, COSV51516013; called by muse, mutect2, varscan2
- ATP2A1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs368388257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A2 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1201260065, COSV57876442; called by muse, varscan2
- ATP2A2 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs866972164; called by muse, varscan2
- ATP2A3 | c.1789G>A p.V597I | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs145622255; called by muse, mutect2, varscan2
- ATP2B3 | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV54857993; called by muse, mutect2, varscan2
- ATP2B3 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 111/274 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781989417; called by muse, mutect2, varscan2
- ATP2B3 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs782226811, COSV54843229, COSV99685268; called by muse, mutect2, varscan2
- ATP2B3 | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1557015474, COSV54845611; called by muse, mutect2, varscan2
- ATP4A | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.141); catalogued as rs750910096, COSV52869298; called by muse, mutect2, varscan2
- ATP5F1C | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 70/208 reads (34%) | catalogued as rs764209644; called by muse, varscan2
- ATP5F1D | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs772125787; called by muse, varscan2
- ATP5IF1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as rs556914230; called by muse, mutect2, varscan2
- ATP6V0D2 | c.133C>T p.L45= | Splice Region (SNP) | VAF 9/56 reads (16%) | catalogued as rs899379003; called by muse, mutect2, varscan2
- ATP6V1C1 | c.623T>G p.V208G | Missense Mutation (SNP) | VAF 77/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV67777602; called by muse, mutect2, varscan2
- ATP7B | c.4307A>G p.D1436G | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV54435027; called by muse, mutect2, varscan2
- ATP8A1 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as rs765091187; called by muse, mutect2, varscan2
- ATP8A1 | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as rs1422947869, COSV52541674; called by muse, mutect2, varscan2
- ATP8B1 | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as CD982655; called by muse, mutect2, varscan2
- ATP9B | c.2839G>A p.A947T | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.928); catalogued as COSV56951742; called by muse, mutect2, varscan2
- ATPSCKMT | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs559270054, COSV54726807, COSV99725982; called by muse, varscan2
- ATR | c.5443G>A p.D1815N | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as rs541296140; called by muse, mutect2, varscan2
- ATR | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs1461133998; called by muse, mutect2, varscan2
- ATRIP | c.2152C>T p.R718C (on ENST00000320211 / NM_130384.3; = p.R691C on NM_032166.4) | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374761739; called by muse, mutect2, varscan2
- ATRN | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs761699255, COSV53523741; called by muse, mutect2, varscan2
- ATXN2 | c.3350G>A p.S1117N (on ENST00000550104; = p.S957N on NM_002973.4) | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.107); catalogued as rs1325259789, COSV101112744; called by muse, mutect2, varscan2
- ATXN3 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as rs199876727, COSV61496947; called by muse, mutect2, varscan2
- ATXN7 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs369372603; called by muse, mutect2, varscan2
- AUNIP | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV65352526; called by muse, mutect2, varscan2
- AVL9 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543517595, COSV59464681; called by muse, mutect2, varscan2
- AVPI1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs544820695, COSV65697467; called by muse, mutect2, varscan2
- AXDND1 | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62645197; called by muse, mutect2, varscan2
- AXDND1 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs752482764; called by muse, mutect2, varscan2
- B3GAT1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs1374536721; called by muse, mutect2, varscan2
- B4GALNT4 | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.258); catalogued as rs774790690, COSV57326872; called by muse, mutect2, varscan2
- B4GALT2 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs762532434, COSV52543802; called by muse, varscan2
- B4GALT2 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs749541889; called by muse, mutect2, varscan2
- B4GALT5 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs752506342, COSV100866998, COSV99056813; called by muse, mutect2, varscan2
- BACH2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57590039, COSV57592010; called by muse, mutect2, varscan2
- BAG4 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.707); catalogued as rs770041398, COSV54861341, COSV54862630; called by muse, mutect2, varscan2
- BAG5 | c.974dup p.N325Kfs*23 | Frame Shift Ins (INS) | VAF 54/122 reads (44%) | catalogued as rs1002009532; called by mutect2, varscan2
- BAIAP2 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 97/253 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766637531, COSV58340913; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1151A>G p.D384G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs770765810; called by mutect2, varscan2
- BAIAP2L2 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372997857; called by muse, mutect2, varscan2
- BAIAP2L2 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1250645326, COSV60201557, COSV60202209; called by muse, mutect2, varscan2
- BAIAP3 | c.3038G>A p.R1013H | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373914532; called by muse, mutect2, varscan2
- BAK1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs745860609, COSV62349465; called by muse, mutect2, varscan2
- BARD1 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779468443, COSV53610495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARD1 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53608844; called by muse, varscan2
- BAZ2B | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs373486810; called by muse, mutect2, varscan2
- BBS10 | c.1973A>G p.Y658C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs886049848; called by muse, mutect2, varscan2
- BBS2 | c.1910+1G>A p.X637_splice | Splice Site (SNP) | VAF 61/146 reads (42%) | catalogued as rs757391646, CS1414370; called by muse, mutect2, varscan2
- BBS2 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.182); catalogued as COSV55329686; called by muse, mutect2, varscan2
- BBS9 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as rs899716022, COSV54157337; called by muse, mutect2, varscan2
- BCAR1 | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151313391; called by muse, mutect2, varscan2
- BCAR1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs751023361; called by muse, mutect2, varscan2
- BCHE | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs764502386; called by muse, varscan2
- BCL2L15 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.809); catalogued as rs757973338; called by muse, mutect2, varscan2
- BCL3 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as COSV51234067; called by muse, mutect2, varscan2
- BCL9 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs587637107, COSV52347592; called by muse, mutect2, varscan2
- BCOR | c.4478G>A p.R1493Q (on ENST00000378444 / NM_001123385.2; = p.R1459Q on NM_017745.6) | Missense Mutation (SNP) | VAF 129/292 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV60711149; called by muse, mutect2, varscan2
- BCORL1 | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 111/265 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs776306357, COSV54397567; called by muse, mutect2, varscan2
- BCORL1 | c.3793C>T p.R1265C | Missense Mutation (SNP) | VAF 97/672 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as rs1464137864, COSV54393793; called by muse, varscan2
- BEAN1 | c.406G>A p.V136M (on ENST00000536005 / NM_001178020.3; = p.V27M on NM_001136106.5) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs578091929; called by muse, mutect2, varscan2
- BECN1 | c.734A>G p.D245G | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1225679982; called by muse, mutect2, varscan2
- BEGAIN | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.481); catalogued as rs773465732, COSV62068155; called by muse, mutect2, varscan2
- BEND2 | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs750510729; called by muse, mutect2, varscan2
- BEND5 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.61); catalogued as COSV65717892; called by muse, mutect2, varscan2
- BEND6 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs200334204; called by muse, mutect2, varscan2
- BEST4 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 131/359 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs774495129, COSV64734160; called by muse, mutect2, varscan2
- BHLHA15 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs764083227; called by muse, mutect2, varscan2
- BICC1 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs1046249158, COSV54067305; called by muse, mutect2, varscan2
- BICDL1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs550764256, COSV99984726; called by muse, mutect2, varscan2
- BICRA | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1013381999; called by muse, mutect2, varscan2
- BIRC6 | c.7319C>T p.A2440V | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.193); catalogued as rs1298167873; called by muse, mutect2, varscan2
- BIRC7 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs775279603, COSV53901161; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); catalogued as rs770246574, COSV63246779; called by muse, mutect2, varscan2
- BLNK | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 42/99 reads (42%) | catalogued as rs200501515; called by muse, mutect2, varscan2
- BLVRA | c.15C>T p.P5= | Splice Region (SNP) | VAF 38/93 reads (41%) | catalogued as rs11545804, COSV55513704; called by muse, mutect2, varscan2
- BMP1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs1337481869, COSV59244514; called by muse, mutect2, varscan2
- BMP1 | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs535986716; called by muse, mutect2, varscan2
- BMP15 | c.625T>G p.C209G | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV53142309; called by muse, mutect2, varscan2
- BMS1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs200858231, COSV100996849; called by muse, mutect2, varscan2
- BMX | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564551; called by muse, mutect2, varscan2
- BMX | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 119/317 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs767793685; called by muse, mutect2, varscan2
- BMX | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53028315; called by muse, mutect2, varscan2
- BNC2 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs1181349194; called by muse, mutect2, varscan2
- BNC2 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as COSV101032591; called by muse, mutect2, varscan2
- BOC | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.362); catalogued as rs751976756, COSV56349674; called by muse, varscan2
- BOD1 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.022); catalogued as rs757098185; called by muse, varscan2
- BOD1L1 | c.7090T>C p.S2364P | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV50028170; called by muse, mutect2, varscan2
- BOP1 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs1045629687; called by muse, mutect2, varscan2
- BPI | c.695C>A p.S232Y (on ENST00000262865; = p.S228Y on NM_001725.3) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs578216988; called by muse, mutect2, varscan2
- BPTF | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs765262835; called by muse, mutect2, varscan2
- BRAP | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as rs1225143986; called by muse, mutect2, varscan2
- BRAT1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs745563920, COSV61397659; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA1 | c.4328G>A p.R1443Q | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs4986849; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 112/268 reads (42%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.481); catalogued as rs1169190081; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD1 | c.2711C>T p.A904V (on ENST00000216267 / NM_001349940.1; = p.A1035V on NM_001304808.3) | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as rs563026361, COSV53454922; called by muse, mutect2, varscan2
- BRD1 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as rs745528936, COSV99349444; called by muse, mutect2, varscan2
- BRD4 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs1348283029; called by muse, varscan2
- BRICD5 | c.751G>A p.V251M (on ENST00000562360; = p.V219M on NM_182563.3) | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.184); catalogued as rs762825593; called by muse, mutect2, varscan2
- BRINP1 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs145481722; called by muse, mutect2, varscan2
- BRINP2 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV64176712; called by muse, mutect2, varscan2
- BRINP2 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 118/281 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.343); catalogued as rs369411788, COSV64181101; called by muse, mutect2, varscan2
- BRINP3 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1014412087; called by muse, mutect2, varscan2
- BRIP1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 96/238 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.267); catalogued as rs913184257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs1555618429, COSV51997205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BROX | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs1483364255; called by muse, mutect2, varscan2
- BRPF1 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1251241565; called by muse, mutect2, varscan2
- BRPF3 | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762968268; called by muse, mutect2, varscan2
- BRSK1 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 129/336 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs753486933, COSV58665688; called by muse, varscan2
- BRSK1 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs1015322634; called by muse, varscan2
- BRWD1 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 145/345 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766554156; called by muse, mutect2, varscan2
- BRWD3 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs1306440344, COSV100956347, COSV64750551; called by muse, mutect2, varscan2
- BRWD3 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 191/458 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100955693; called by muse, varscan2
- BSCL2 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772536764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.2065G>A p.G689S | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761942790, COSV99608489; called by muse, mutect2, varscan2
- BSN | c.10967G>A p.R3656H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367981179; called by muse, mutect2, varscan2
- BTAF1 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs777326643, COSV99796047; called by muse, mutect2, varscan2
- BTAF1 | c.4792G>A p.E1598K | Missense Mutation (SNP) | VAF 89/241 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs530875744, COSV56435131; called by muse, mutect2, varscan2
- BTBD11 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.301); catalogued as rs771116406; called by muse, mutect2, varscan2
- BTBD18 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1359017431, COSV104376712; called by muse, mutect2, varscan2
- BTK | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM040689, CM980262, COSV58117488; called by muse, varscan2
- BTNL8 | c.847G>A p.A283T (on ENST00000340184 / NM_001040462.3; = p.R326H on NM_024850.2) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs761560506; called by muse, mutect2, varscan2
- BYSL | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1157979245; called by muse, mutect2, varscan2
- C10orf71 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1287157255, COSV60506726; called by muse, mutect2, varscan2
- C10orf95 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.26); catalogued as rs778107247; called by muse, mutect2, varscan2
- C11orf68 | c.584C>T p.A195V (on ENST00000530188; = p.A236V on NM_031450.4) | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.389); catalogued as rs1259948006; called by muse, mutect2, varscan2
- C11orf94 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs540548996, COSV53798843; called by muse, mutect2, varscan2
- C12orf40 | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 182/486 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1188977866, COSV104410247, COSV61134900, COSV61138477; called by muse, mutect2, varscan2
- C12orf71 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs763196274, COSV70282645; called by muse, mutect2, varscan2
- C15orf62 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as rs771398272, COSV99548987; called by muse, mutect2, varscan2
- C16orf70 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.928); catalogued as rs149407168; called by muse, mutect2, varscan2
- C16orf72 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV100589121; called by muse, mutect2, varscan2
- C17orf64 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1417608936, COSV52257726; called by muse, varscan2
- C17orf67 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.923); catalogued as rs766096754, COSV101190892; called by muse, mutect2, varscan2
- C17orf78 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs765382130; called by muse, mutect2, varscan2
- C19orf47 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as rs753412216; called by muse, mutect2, varscan2
- C19orf71 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs754300947; called by muse, mutect2, varscan2
- C1GALT1 | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs754178446; called by muse, mutect2, varscan2
- C1QTNF1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs375349048; called by muse, mutect2, varscan2
- C1QTNF1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.197); catalogued as rs776839033, COSV59260951; called by muse, mutect2, varscan2
- C1QTNF9B | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 59/88 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375375921; called by muse, mutect2, varscan2
- C1RL | c.617-8C>T | Splice Region (SNP) | VAF 31/105 reads (30%) | catalogued as rs966312966; called by muse, mutect2, varscan2
- C1S | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs1555163103, COSV61071827; called by muse, varscan2
- C1S | c.2003T>C p.V668A | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs782166182; called by muse, varscan2
- C1orf115 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1246633378; called by muse, mutect2, varscan2
- C1orf141 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as rs752539243, COSV63992303; called by muse, mutect2, varscan2
- C1orf167 | c.3388G>A p.A1130T | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.249); catalogued as rs1043022403; called by muse, mutect2, varscan2
- C1orf216 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs1197057749; called by muse, mutect2, varscan2
- C1orf54 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as rs1553853100; called by muse, mutect2, varscan2
- C1orf94 | c.640G>A p.A214T (on ENST00000488417 / NM_001134734.2; = p.A24T on NM_032884.5) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs202207825, COSV64913085; called by muse, mutect2, varscan2
- C20orf194 | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs779904443, COSV52691248; called by muse, mutect2, varscan2
- C2CD3 | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 63/151 reads (42%) | catalogued as rs1382351297, COSV58092490; called by muse, mutect2, varscan2
- C2CD3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759547604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, mutect2, varscan2
- C2CD6 | c.1855del p.I619Lfs*19 | Frame Shift Del (DEL) | VAF 30/71 reads (42%) | catalogued as rs752496395; called by mutect2, varscan2
- C2orf16 | c.3307C>T p.P1103S | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs760303267; called by muse, mutect2, varscan2
- C2orf16 | c.4916G>A p.R1639H | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs199903910, COSV62675239; called by muse, mutect2, varscan2
- C2orf16 | c.5515C>T p.R1839C | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1233876003, COSV100820631; called by muse, mutect2, varscan2
- C2orf69 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as COSV60666837; called by muse, mutect2, varscan2
- C2orf78 | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs973739443; called by muse, mutect2, varscan2
- C3AR1 | c.1418T>C p.V473A | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV50820746; called by muse, mutect2, varscan2
- C5AR2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.061); catalogued as rs774806936, COSV99953754; called by muse, mutect2, varscan2
- C6 | c.888T>G p.N296K | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV54715716; called by muse, varscan2
- C6 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184352709; called by muse, mutect2, varscan2
- C7orf31 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs147311660; called by muse, mutect2, varscan2
- C8orf37 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 223/562 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752701566; called by muse, mutect2, varscan2
- C8orf58 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.32); catalogued as rs771271445; called by muse, mutect2, varscan2
- C8orf82 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1289918651; called by muse, mutect2, varscan2
- C9orf131 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs764495713; called by muse, mutect2, varscan2
- C9orf24 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as rs1250294736; called by muse, mutect2, varscan2
- C9orf64 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs200742205; called by muse, mutect2, varscan2
- CA3 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as rs557757657, COSV99570848; called by muse, mutect2, varscan2
- CAAP1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100445204; called by muse, mutect2, varscan2
- CAB39 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as rs757388040, COSV51475109; called by muse, mutect2, varscan2
- CAB39 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs1366529396; called by muse, mutect2, varscan2
- CABIN1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs777119818, COSV54078153; called by muse, mutect2, varscan2
- CABIN1 | c.4933C>T p.R1645C | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1221409667; called by muse, mutect2, varscan2
- CABIN1 | c.5593C>T p.R1865C | Missense Mutation (SNP) | VAF 84/210 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1434378133, COSV54090063; called by muse, mutect2, varscan2
- CABP2 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs1353573433; called by muse, mutect2, varscan2
- CABP7 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765114031; called by muse, mutect2, varscan2
- CACFD1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT tolerated (0.08); PolyPhen benign (0.217); catalogued as rs782678068, COSV52469040; called by muse, mutect2, varscan2
- CACHD1 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1235538167, COSV51557130, COSV51562484; called by muse, mutect2, varscan2
- CACHD1 | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 110/296 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as rs748338922; called by muse, mutect2, varscan2
- CACNA1A | c.6178G>A p.D2060N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs761560224; ClinVar: uncertain significance; called by muse, varscan2
- CACNA1A | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64194248; called by muse, mutect2, varscan2
- CACNA1B | c.1906A>G p.N636D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as COSV53128519; called by muse, mutect2, varscan2
- CACNA1B | c.3481G>A p.A1161T | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.234); catalogued as rs200326973; called by muse, mutect2, varscan2
- CACNA1B | c.5329C>T p.R1777C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV53120518; called by muse, mutect2, varscan2
- CACNA1E | c.6548C>T p.S2183F (on ENST00000367573 / NM_001205293.3; = p.S2140F on NM_000721.4) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV62398299; called by muse, mutect2, varscan2
- CACNA1F | c.2161A>G p.I721V | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs782701503; called by muse, mutect2, varscan2
- CACNA1G | c.1070T>C p.V357A | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV100662457; called by muse, mutect2, varscan2
- CACNA1G | c.6364C>T p.R2122C | Missense Mutation (SNP) | VAF 100/294 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1320478495; called by muse, mutect2, varscan2
- CACNA1H | c.6748C>T p.R2250C | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs375586314; called by muse, mutect2, varscan2
- CACNA1S | c.4975G>A p.A1659T | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100755077; called by muse, varscan2
- CACNA1S | c.3853G>A p.G1285S | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768535906, COSV62940596, COSV62941559; called by muse, varscan2
- CACNA1S | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 121/264 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762032797, COSV62936102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D4 | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 92/234 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs778241147; called by muse, mutect2, varscan2
- CACNA2D4 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs754788510, COSV54959895; called by muse, mutect2, varscan2
- CACNA2D4 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV54944484; called by muse, mutect2, varscan2
- CACNB2 | c.353C>T p.A118V (on ENST00000324631 / NM_201596.3; = p.A63V on NM_000724.4) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs371859398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB2 | c.1123G>A p.A375T (on ENST00000324631 / NM_201596.3; = p.A320T on NM_000724.4) | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs552868927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNB2 | c.1312G>A p.D438N (on ENST00000324631 / NM_201596.3; = p.D383N on NM_000724.4) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778466195, COSV56612862; called by muse, mutect2, varscan2
- CACNB3 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs901128138, COSV56396951; called by muse, mutect2, varscan2
- CACNB4 | c.621G>A p.T207= | Splice Region (SNP) | VAF 55/151 reads (36%) | catalogued as rs778919621, COSV52397102; called by muse, varscan2
- CACTIN | c.1942C>T p.R648C | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50267561; called by muse, mutect2, varscan2
- CADM4 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs867442079, COSV99731734; called by muse, mutect2, varscan2
- CADM4 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55929267, COSV99731474; called by muse, mutect2, varscan2
- CADPS | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752617298; called by muse, mutect2, varscan2
- CALD1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1267886086, COSV62649429, COSV62650905; called by muse, varscan2
- CALHM3 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV63921932; called by muse, mutect2, varscan2
- CALML3 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs1011051689, COSV100178810; called by muse, mutect2, varscan2
- CALML5 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1482623360, COSV66702680; called by muse, mutect2, varscan2
- CALN1 | c.22G>A p.A8T (on ENST00000329008 / NM_001017440.3; = p.A50T on NM_031468.4) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs767526121, COSV61141568; called by muse, mutect2, varscan2
- CAMK1D | c.596G>A p.S199N | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV66615905; called by muse, mutect2, varscan2
- CAMK1D | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257797457, COSV66610289; called by muse, mutect2, varscan2
- CAMK2B | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1039889497, COSV51661261, COSV51661783; called by muse, varscan2
- CAMK4 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99998367; called by muse, mutect2, varscan2
- CAMKK2 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs763899089; called by muse, mutect2, varscan2
- CAMKK2 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs768616526, COSV100242996, COSV61215096; called by muse, mutect2, varscan2
- CAMSAP3 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs774857030, COSV50335769; called by muse, mutect2, varscan2
- CAMSAP3 | c.2468G>A p.R823H | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs768879606; called by muse, varscan2
- CAMSAP3 | c.2737C>T p.R913* | Nonsense Mutation (SNP) | VAF 134/325 reads (41%) | catalogued as rs372709226; called by muse, mutect2, varscan2
- CAMTA1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.125); catalogued as rs754160101, COSV57924632; called by muse, mutect2, varscan2
- CAMTA2 | c.2254G>A p.V752M | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs200135418; called by muse, mutect2, varscan2
- CAMTA2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61835643; called by muse, mutect2, varscan2
- CAND1 | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs764897319; called by muse, mutect2, varscan2
- CAND2 | c.1898C>T p.A633V (on ENST00000456430 / NM_001162499.2; = p.A540V on NM_012298.3) | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); catalogued as rs749368878, COSV55993503; called by muse, mutect2, varscan2
- CAND2 | c.2233C>T p.R745C (on ENST00000456430 / NM_001162499.2; = p.R652C on NM_012298.3) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as rs751564346; called by muse, mutect2, varscan2
- CAPN10 | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs748401959, COSV54375519; called by muse, mutect2, varscan2
- CAPN11 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs373070433, COSV101291935; called by muse, mutect2, varscan2
- CAPN12 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1237507066; called by muse, mutect2, varscan2
- CAPN13 | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171686520; called by muse, mutect2, varscan2
- CAPN5 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs782464684, COSV53688556; called by muse, mutect2, varscan2
- CAPRIN1 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs1405472982; called by muse, mutect2, varscan2
- CAPS | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs202009632; called by muse, mutect2, varscan2
- CAPZA1 | c.105C>T p.D35= | Splice Region (SNP) | VAF 29/84 reads (35%) | catalogued as rs766268171; called by muse, mutect2, varscan2
- CARD11 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as rs753952757, COSV62754608; called by muse, mutect2, varscan2
- CARD11 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV67801365; called by muse, mutect2, varscan2
- CARD16 | c.11A>C p.K4T | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as rs61745000; called by muse, mutect2, varscan2
- CARD6 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54565082; called by muse, mutect2, varscan2
- CARD8 | c.736G>A p.A246T (on ENST00000651546 / NM_001184900.3; = p.A196T on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs547827116; called by muse, mutect2, varscan2
- CARMIL2 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1468078419; called by muse, mutect2, varscan2
- CASK | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); catalogued as COSV100587412; called by muse, mutect2, varscan2
- CASKIN1 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1176560713; called by muse, mutect2, varscan2
- CASP10 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.084); catalogued as rs773537509; called by muse, mutect2, varscan2
- CASP14 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 192/462 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as rs149050628; called by muse, mutect2, varscan2
- CASP2 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as rs756033852; called by muse, mutect2, varscan2
- CASP5 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs139013723; called by muse, mutect2
- CASP8AP2 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as rs758643574, COSV52746227; called by muse, mutect2, varscan2
- CASQ1 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as rs190698081, COSV63624135; called by muse, mutect2, varscan2
- CASS4 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs767728589, COSV64386016; called by muse, varscan2
- CASZ1 | c.4246C>T p.R1416W | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs772938935, COSV65456081; called by muse, mutect2, varscan2
- CASZ1 | c.3529G>A p.A1177T | Missense Mutation (SNP) | VAF 139/336 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.32); catalogued as rs572865002; called by muse, varscan2
- CASZ1 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470591711, COSV59739493; called by muse, mutect2, varscan2
- CATSPERD | c.1509G>A p.S503= | Splice Region (SNP) | VAF 13/52 reads (25%) | catalogued as rs766707672, COSV58464186; called by muse, mutect2, varscan2
- CATSPERE | c.2044C>T p.R682* | Nonsense Mutation (SNP) | VAF 34/79 reads (43%) | catalogued as rs1442164237, COSV63676392; called by muse, varscan2
- CBARP | c.938G>A p.R313H (on ENST00000382477; = p.R293H on NM_152769.3) | Missense Mutation (SNP) | VAF 95/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs771141586; called by muse, mutect2, varscan2
- CBARP | c.392C>T p.A131V (on ENST00000382477; = p.A137V on NM_152769.3) | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs534006111, COSV99289583; called by muse, mutect2, varscan2
- CBLN3 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368781428; called by muse, mutect2, varscan2
- CBX3 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1208793747, COSV61761621; called by muse, mutect2, varscan2
- CC2D1A | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs372880706; called by muse, mutect2, varscan2
- CC2D1B | c.1532T>C p.V511A | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs956375402; called by muse, mutect2, varscan2
- CCAR2 | c.2203C>T p.R735W | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.451); catalogued as rs201102472, COSV52387117; called by muse, mutect2, varscan2
- CCDC102B | c.1542A>T p.*514Yext*7 | Nonstop Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV60137542; called by muse, mutect2, varscan2
- CCDC114 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs761311942; called by muse, varscan2
- CCDC116 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs967272795, COSV53039204, COSV99489292; called by muse, mutect2, varscan2
- CCDC130 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764972453; called by muse, mutect2, varscan2
- CCDC136 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1485439992; called by muse, mutect2, varscan2
- CCDC137 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769984058, COSV61303643, COSV61303730; called by muse, mutect2, varscan2
- CCDC142 | c.1718C>T p.A573V (on ENST00000393965 / NM_001365575.2; = p.A566V on NM_032779.4) | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.248); catalogued as COSV50688439; called by muse, mutect2, varscan2
- CCDC146 | c.1208C>A p.S403Y | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.178); catalogued as COSV53546491; called by muse, mutect2, varscan2
- CCDC148 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs757099970, COSV51772201; called by muse, mutect2, varscan2
- CCDC150 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs373323546; called by muse, mutect2, varscan2
- CCDC154 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.83); catalogued as rs932034293, COSV99247166; called by muse, mutect2, varscan2
- CCDC168 | c.2552A>G p.Q851R | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs1162657126; called by muse, varscan2
- CCDC168 | c.2510C>T p.T837M | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1441965877, COSV70555471; called by muse, varscan2
- CCDC168 | c.2485A>G p.T829A | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs376332428; called by muse, varscan2
- CCDC171 | c.2968C>T p.R990C | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs753856863, COSV52641994; called by muse, mutect2, varscan2
- CCDC183 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.725); catalogued as rs761080958; called by muse, varscan2
- CCDC185 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.142); catalogued as rs1002892374, COSV64821784; called by muse, mutect2, varscan2
- CCDC189 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs146729147; called by muse, mutect2, varscan2
- CCDC198 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs755799407; called by muse, mutect2, varscan2
- CCDC39 | c.210G>A p.Q70= | Splice Region (SNP) | VAF 7/61 reads (11%) | catalogued as rs1202389588; called by muse, mutect2, varscan2
- CCDC40 | c.3244C>T p.R1082C | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1055443134, COSV100162801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC47 | c.72T>G p.D24E | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV56722281; called by muse, mutect2, varscan2
- CCDC57 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs559421961; called by muse, mutect2, varscan2
- CCDC60 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV59550968; called by muse, mutect2, varscan2
- CCDC63 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs143128187, COSV57527702; called by muse, varscan2
- CCDC66 | c.1496G>A p.R499H (on ENST00000394672 / NM_001353147.1; = p.R465H on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 146/355 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs370201168; called by muse, mutect2, varscan2
- CCDC7 | c.3811C>T p.R1271C | Missense Mutation (SNP) | VAF 200/454 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1415188403, COSV56550300; called by muse, mutect2, varscan2
- CCDC71 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1320969451, COSV58910513; called by muse, mutect2, varscan2
- CCDC73 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV58796365; called by muse, mutect2, varscan2
- CCDC80 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1388319525, COSV52815430; called by muse, mutect2, varscan2
- CCDC82 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs768645326, COSV53595144; called by muse, mutect2, varscan2
- CCDC85C | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs1482643321; called by muse, mutect2
- CCDC87 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as rs749421239, COSV59580223; called by muse, mutect2, varscan2
- CCDC88A | c.4980A>G p.I1660M (on ENST00000436346 / NM_001365480.1; = p.I1632M on NM_018084.5) | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV104375725; called by muse, mutect2, varscan2
- CCDC88A | c.4592C>T p.A1531V (on ENST00000436346 / NM_001365480.1; = p.A1503V on NM_018084.5) | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs775263452, COSV55066799; called by muse, mutect2, varscan2
- CCDC88B | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1376200030; called by muse, mutect2, varscan2
- CCDC88B | c.3257G>A p.R1086Q | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs370433115; called by muse, mutect2, varscan2
- CCDC88B | c.3581C>T p.A1194V | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs1216173941; called by muse, mutect2, varscan2
- CCDC88C | c.5630G>A p.R1877H | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs747824457; called by muse, mutect2, varscan2
- CCDC88C | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs778210068; called by muse, mutect2, varscan2
- CCDC89 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); catalogued as rs570614928, COSV100320928, COSV57034716; called by muse, mutect2, varscan2
- CCDC97 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as rs1286685402, COSV54189870; called by muse, mutect2, varscan2
- CCDC97 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as rs1357572445; called by muse, mutect2, varscan2
- CCER1 | c.103T>C p.W35R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs1249205856, COSV100727139; called by muse, mutect2, varscan2
- CCL13 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56774687; called by muse, mutect2, varscan2
- CCL27 | c.201C>T p.F67= | Splice Region (SNP) | VAF 24/61 reads (39%) | catalogued as rs777608775, COSV52405724; called by muse, mutect2, varscan2
- CCNA2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs760400347; called by muse, mutect2, varscan2
- CCNB1IP1 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100738561; called by muse, mutect2, varscan2
- CCNDBP1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs115573144; called by muse, mutect2, varscan2
- CCNH | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.318); catalogued as rs922162838; called by muse, mutect2, varscan2
- CCNL2 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs374382413; called by muse, mutect2, varscan2
- CCNT2 | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1214539684; called by muse, mutect2, varscan2
- CCNY | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1244361318, COSV99590312; called by muse, mutect2, varscan2
- CCNY | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749701305; called by muse, mutect2, varscan2
12,925 further variants in this file (8,497 protein-altering or splice-affecting, 3,552 silent, 876 other) are not listed here.
